Somatic mutation profile of tumor specimen 0E1KOH from CCDI case PBCVTW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1KOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d88be04e-29da-4b61-bdb8-71dd41542066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KOA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3175a2ee-abe2-4de5-8737-fa1232d63f09

The open-access MAF lists 45 somatic variants for this specimen: 22 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 14, Intron 5, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECT2L | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 120/348 reads (34%) | catalogued as COSV62882800; called by muse, varscan2
- POGLUT1 | c.733A>G p.M245V | Missense Mutation (SNP) | VAF 198/568 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs368566548; ClinVar: uncertain significance; called by muse, varscan2
- SH3PXD2B | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61124843; called by muse, varscan2
- ATAD3A | c.1577A>T p.Q526L | Missense Mutation (SNP) | VAF 138/336 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, varscan2
- C17orf97 | c.270G>T p.R90S | Missense Mutation (SNP) | VAF 124/346 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, varscan2
- CEL | c.1567G>A p.E523K (on ENST00000673714; = p.E520K on NM_001807.6) | Missense Mutation (SNP) | VAF 116/608 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, varscan2
- CLCN1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 298/560 reads (53%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.277); called by muse, varscan2
- CTTNBP2 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 151/303 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, varscan2
- DOCK3 | c.4767+1G>A p.X1589_splice | Splice Site (SNP) | VAF 109/164 reads (66%) | called by muse, varscan2
- ECT2 | c.1580A>G p.D527G (on ENST00000392692 / NM_001349098.2; = p.D496G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 160/500 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, varscan2
- ELP3 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 138/355 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, varscan2
- GLP1R | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- MUC22 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 152/364 reads (42%) | SIFT tolerated (0.3); called by muse, varscan2
- MUC5B | c.8384C>G p.P2795R | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, varscan2
- NEU1 | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 134/292 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, varscan2
- NOS1AP | c.1224G>T p.L408F | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, varscan2
- PRKCA | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 158/694 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- SMG8 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 122/605 reads (20%) | called by muse, varscan2
- TEX45 | c.758G>T p.R253M | Missense Mutation (SNP) | VAF 88/136 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.443); called by muse, varscan2
- UBQLN3 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 220/285 reads (77%) | called by muse, varscan2
- WNK4 | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 174/654 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, varscan2
- ZNF292 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 176/528 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, varscan2
- ABCC4 | c.3054C>T p.D1018= | Silent (SNP) | VAF 108/339 reads (32%) | called by muse, varscan2
- CTSC | c.354C>T p.C118= | Silent (SNP) | VAF 159/256 reads (62%) | called by muse, varscan2
- EPDR1 | c.498C>A p.I166= | Silent (SNP) | VAF 80/387 reads (21%) | catalogued as COSV52261767; called by muse, varscan2
- FMOD | c.360C>A p.I120= | Silent (SNP) | VAF 142/518 reads (27%) | catalogued as COSV61610519; called by muse, varscan2
- GCLC | c.1914C>T p.S638= (on ENST00000643939; = p.S636= on NM_001498.4) | Silent (SNP) | VAF 90/230 reads (39%) | called by muse, varscan2
- HAX1 | c.702C>T p.G234= | Silent (SNP) | VAF 156/436 reads (36%) | catalogued as COSV55178177; called by muse, varscan2
- HOXB2 | c.879C>T p.D293= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as rs763009865; called by muse, varscan2
- KLHL10 | c.84C>A p.I28= | Silent (SNP) | VAF 110/425 reads (26%) | called by muse, varscan2
- KRTAP12-4 | c.48C>G p.G16= | Silent (SNP) | VAF 106/302 reads (35%) | called by muse, varscan2
- PCDHGA10 | c.1098G>T p.L366= | Silent (SNP) | VAF 105/337 reads (31%) | catalogued as COSV53931053; called by muse, varscan2
- SLC1A6 | c.1611C>A p.P537= | Silent (SNP) | VAF 84/242 reads (35%) | called by muse, varscan2
- SRRM2 | c.3363C>T p.F1121= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs367767197, COSV57070923; called by muse, varscan2
- STAB2 | c.4737A>G p.E1579= | Silent (SNP) | VAF 114/348 reads (33%) | called by muse, varscan2
- ZBTB33 | c.1473G>A p.R491= | Silent (SNP) | VAF 138/200 reads (69%) | catalogued as rs782757193; called by muse, varscan2
- CCDC60 | c.*77C>T | 3'UTR (SNP) | VAF 23/119 reads (19%) | catalogued as rs1198937556; called by muse, varscan2
- CEBPZ | c.156+83G>T | Intron (SNP) | VAF 18/58 reads (31%) | called by muse, varscan2
- CHODL | c.*95G>T | 3'UTR (SNP) | VAF 132/380 reads (35%) | catalogued as rs755599558, COSV53042294; called by muse, varscan2
- DHRS2 | c.540+79A>C | Intron (SNP) | VAF 20/60 reads (33%) | called by muse, varscan2
- LDLRAP1 | c.747+9T>C | Intron (SNP) | VAF 56/141 reads (40%) | called by muse, varscan2
- MUCL3 | c.946+1240C>T | Intron (SNP) | VAF 133/374 reads (36%) | called by muse, varscan2
- PAX1 | c.-39C>T | 5'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, varscan2
- PAX1 | c.-38G>T | 5'UTR (SNP) | VAF 21/52 reads (40%) | catalogued as rs1350798001; called by muse, varscan2
- RHBDL2 | c.-125-14C>A | Intron (SNP) | VAF 62/198 reads (31%) | called by muse, varscan2
